Somatic mutation profile of tumor specimen TCGA-AA-3866-01A (aliquot TCGA-AA-3866-01A-01W-0995-10) from TCGA case TCGA-AA-3866, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 78.5 years (28,672 days).
Specimen TCGA-AA-3866-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c059932-a25d-48fd-b23f-2a0c9e776c0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3866-10A (Blood Derived Normal), aliquot TCGA-AA-3866-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d683bb7-60cc-490a-8024-b98b1c14974d

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 33 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 33, Nonsense Mutation 9, Intron 3, Splice Site 3, Frame Shift Ins 3, 3'UTR 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894068, CM970407, COSV52827729; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 46/207 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as CM126689, COSV55903618; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-1G>C p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 491/1082 reads (45%) | hotspot (GDC flag); catalogued as COSV57125628, COSV57128950, COSV99163201; called by muse, mutect2, varscan2
- TP53 | c.528C>A p.C176* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | hotspot (GDC flag); catalogued as COSV52687391, COSV52701599, COSV52735850, COSV99377692; called by muse, mutect2, varscan2
- ACE | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52008260; called by muse, mutect2, varscan2
- ACO2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs534016929, COSV53441699; called by muse, mutect2, varscan2
- ADGRE2 | c.2464-1G>C p.X822_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100216134; called by muse, mutect2, varscan2
- AHR | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 65/574 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769847453, COSV54123788; called by muse, mutect2, varscan2
- ANKRD13A | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1263330241, COSV55677125; called by muse, mutect2, varscan2
- APC | c.3103C>T p.Q1035* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as CM106362, COSV57349980; called by muse, mutect2, varscan2
- APC | c.3911dup p.A1305Sfs*10 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | catalogued as COSV57350327; called by mutect2, pindel, varscan2
- BMI1 | c.221C>G p.T74S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1389866664, COSV64959188; called by muse, mutect2, varscan2
- CACNG7 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437342585, COSV99712078, COSV99712205; called by muse, mutect2, varscan2
- CCDC173 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 188/613 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV101352360, COSV69572556; called by muse, mutect2, varscan2
- CDH17 | c.1862G>T p.S621I | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV99217527; called by muse, mutect2, varscan2
- CYP2F1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs763970224, COSV100462774; called by muse, mutect2, varscan2
- DDX60 | c.5118G>T p.W1706C | Missense Mutation (SNP) | VAF 130/512 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV67097238; called by muse, mutect2, varscan2
- ELMO1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 65/507 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs919445189, COSV60304331; called by muse, mutect2, varscan2
- ESX1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as COSV101006465; called by muse, mutect2, varscan2
- ETAA1 | c.699T>G p.D233E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV55473502; called by muse, mutect2, varscan2
- EXOC6 | c.2338C>T p.R780* | Nonsense Mutation (SNP) | VAF 43/89 reads (48%) | catalogued as rs760629495, COSV53319461; called by muse, mutect2, varscan2
- FAM199X | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 56/213 reads (26%) | catalogued as COSV55433869; called by muse, mutect2, varscan2
- FBN3 | c.4009G>A p.D1337N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99561133; called by muse, mutect2, varscan2
- GLI3 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 89/725 reads (12%) | catalogued as HM971692, COSV67889135; called by muse, mutect2, varscan2
- GPC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs372530892, COSV65605013, COSV65615616; called by muse, mutect2, varscan2
- GRIK3 | c.2518G>A p.V840M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs773086718, COSV100902116; called by muse, mutect2, varscan2
- HNRNPUL1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs144715337; called by muse, mutect2, varscan2
- IGLON5 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs536652682, COSV54536407; called by muse, mutect2, varscan2
- IL17RA | c.341T>A p.L114* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as rs1410167311, COSV100083201; called by muse, mutect2, varscan2
- IMP4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs749756016, COSV52091922, COSV52091941; called by muse, mutect2, varscan2
- INPP1 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs777831500, COSV59416213; called by muse, mutect2, varscan2
- JMJD1C | c.3076C>T p.L1026F | Missense Mutation (SNP) | VAF 98/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59513446, COSV59518627; called by muse, mutect2, varscan2
- JSRP1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV55555281; called by muse, mutect2, varscan2
- KCNQ3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479652323, COSV66467913, COSV66472703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA0232 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs367656934; called by muse, varscan2
- KIAA1109 | c.9673-2A>T p.X3225_splice | Splice Site (SNP) | VAF 39/79 reads (49%) | catalogued as COSV99165410; called by muse, mutect2, varscan2
- KIF1A | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs771284647, COSV100241320; called by muse, mutect2, varscan2
- L3MBTL1 | c.1756G>A p.A586T (on ENST00000418998 / NM_001377303.1; = p.A496T on NM_015478.7) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.817); catalogued as rs766968999, COSV64228396; called by muse, mutect2, varscan2
- LRP2 | c.7588G>T p.A2530S | Missense Mutation (SNP) | VAF 256/787 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99788905; called by muse, mutect2, varscan2
- MARCO | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503572, COSV59056535; called by muse, mutect2, varscan2
- MERTK | c.2660G>A p.G887D | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99774777; called by muse, mutect2, varscan2
- NECAB1 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV70240825; called by muse, mutect2, varscan2
- NFASC | c.1346G>A p.R449Q (on ENST00000339876 / NM_001378329.1; = p.R460Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 274/518 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs758966488, COSV58381773; called by muse, mutect2, varscan2
- NPAP1 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs776643326, COSV100275102, COSV61508889; called by mutect2, varscan2
- NUP93 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100360315; called by muse, mutect2, varscan2
- OPN5 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 481/691 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1008543429, COSV55244102; called by muse, mutect2, varscan2
- OR51E1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 123/342 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs146565220; called by muse, mutect2, varscan2
- OR5V1 | c.528C>A p.Y176* | Nonsense Mutation (SNP) | VAF 23/131 reads (18%) | catalogued as COSV65828430; called by muse, mutect2, varscan2
- PABPC4 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV65723916; called by muse, mutect2, varscan2
- PARP11 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 161/411 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57395509; called by muse, mutect2, varscan2
- PCSK5 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.023); catalogued as rs200049619, COSV65085478; called by muse, mutect2, varscan2
- PDE4DIP | c.4131C>A p.S1377R | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.048); catalogued as COSV57700731; called by muse, varscan2
- PLPPR5 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV99587424; called by muse, mutect2, varscan2
- PSMC1 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.953); catalogued as COSV99728378; called by muse, mutect2
- PTBP3 | c.1309C>T p.L437F | Missense Mutation (SNP) | VAF 249/1514 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV57583991; called by muse, mutect2, varscan2
- PTCHD3 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV101438915; called by muse, mutect2, varscan2
- RASGRP3 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 128/840 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs200007507, COSV67822907; called by muse, mutect2, varscan2
- RHD | c.780C>A p.H260Q | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as rs1170243924, COSV59646479; called by muse, mutect2, varscan2
- RPAP1 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.333); catalogued as COSV100427173; called by muse, mutect2, varscan2
- RTL8A | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV66188681; called by muse, mutect2, varscan2
- SAMD9 | c.2537G>A p.R846K | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101180285; called by muse, mutect2, varscan2
- SCFD2 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs149034746, COSV66369541; called by muse, mutect2, varscan2
- SERINC4 | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV51050983; called by muse, mutect2
- SERPINA5 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV61574296; called by muse, mutect2, varscan2
- SLCO4A1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs763020976, COSV53890742; called by muse, mutect2
- SLIT3 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 61/254 reads (24%) | catalogued as rs767508476, COSV60637068; called by muse, mutect2, varscan2
- SUGT1 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs764131039, COSV59422311; called by muse, mutect2, varscan2
- TBC1D9 | c.2862G>C p.Q954H | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101464355; called by muse, mutect2
- TFIP11 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1278453677, COSV53226514; called by muse, varscan2
- TPP2 | c.2998A>G p.T1000A | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101060305; called by muse, mutect2, varscan2
- TSTD2 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 64/508 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99403914; called by muse, mutect2, varscan2
- TTLL2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs374723694; called by muse, mutect2, varscan2
- TTN | c.77565C>A p.D25855E (on ENST00000591111; = p.D18431E on NM_003319.4) | Missense Mutation (SNP) | VAF 89/232 reads (38%) | PolyPhen possibly damaging (0.489); catalogued as COSV100617353; called by muse, mutect2, varscan2
- TUBGCP5 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1352823681; called by muse, mutect2, varscan2
- USHBP1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as rs201299465, COSV99394304; called by muse, mutect2, varscan2
- VANGL2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 127/220 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1314974864, CM114448, COSV63604698; called by muse, mutect2, varscan2
- WDR6 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs769187217, COSV58245078; called by muse, mutect2, varscan2
- ZBTB7A | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59327633; called by muse, mutect2, varscan2
- ZDHHC16 | c.967A>G p.N323D | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs756707854, COSV59135692; called by muse, mutect2, varscan2
- ZNF132 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99571198; called by muse, mutect2, varscan2
- ZNF180 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 171/833 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55421861; called by muse, mutect2, varscan2
- ZNF280C | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 167/408 reads (41%) | catalogued as COSV100921240; called by muse, mutect2, varscan2
- ZNF804A | c.2620C>G p.Q874E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100168367; called by muse, mutect2, varscan2
- BCL9L | c.1188dup p.E397Rfs*22 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- MYT1L | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, varscan2
- SOX9 | c.361A>G p.R121G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2
- SRSF6 | c.932dup p.A312Gfs*18 | Frame Shift Ins (INS) | VAF 20/213 reads (9%) | called by mutect2, pindel
- TEX47 | c.522del p.L175Sfs*15 | Frame Shift Del (DEL) | VAF 142/426 reads (33%) | called by mutect2, pindel, varscan2
- ACHE | c.981G>T p.R327= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs529092085, COSV53818381; called by muse, mutect2, varscan2
- ADRB1 | c.519G>A p.A173= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV65168011; called by muse, mutect2, varscan2
- APCDD1L | c.1191C>T p.N397= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs569125300, COSV100954017; called by muse, mutect2
- CCKBR | c.513G>A p.A171= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV58102428; called by muse, mutect2
- CD109 | c.2673C>T p.G891= | Silent (SNP) | VAF 53/417 reads (13%) | catalogued as COSV54651242; called by muse, mutect2, varscan2
- CDH20 | c.87G>A p.T29= | Silent (SNP) | VAF 58/220 reads (26%) | catalogued as rs1472027632, COSV53011641; called by muse, mutect2, varscan2
- CNTN2 | c.2001C>T p.A667= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs1307242710, COSV59350735; called by muse, mutect2, varscan2
- CSMD1 | c.5805C>T p.N1935= (on ENST00000520002; = p.N1934= on NM_033225.6) | Silent (SNP) | VAF 154/789 reads (20%) | catalogued as rs374441217; called by muse, mutect2, varscan2
- CSPG5 | c.609G>A p.P203= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs199702237; called by muse, mutect2, varscan2
- DLGAP2 | c.2607G>A p.S869= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs374343486; called by muse, mutect2, varscan2
- DNAH2 | c.3363C>T p.N1121= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs201677291, COSV66720895; called by muse, mutect2, varscan2
- EVC2 | c.885C>T p.H295= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs752378780, COSV60395493; ClinVar: likely benign; called by muse, mutect2, varscan2
- FETUB | c.1110G>A p.G370= | Silent (SNP) | VAF 87/235 reads (37%) | catalogued as rs1326741993, COSV54006075; called by muse, mutect2, varscan2
- GRM8 | c.1857C>T p.R619= | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as COSV58805752, COSV58854595; called by muse, mutect2, varscan2
- H2AC16 | c.99A>T p.R33= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV58900384; called by muse, mutect2, varscan2
- KRTAP10-2 | c.681C>T p.P227= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs587745004, COSV100554091; called by muse, mutect2, varscan2
- LPAR3 | c.483G>A p.A161= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs752564044, COSV65453812; called by muse, mutect2, varscan2
- NAV3 | c.4602G>A p.S1534= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1320808846, COSV57086458; called by muse, mutect2, varscan2
- NEU1 | c.258G>A p.P86= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV57667360; called by muse, mutect2, varscan2
- OR13C8 | c.414G>A p.K138= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV58611416; called by muse, mutect2, varscan2
- PLXND1 | c.3508C>T p.L1170= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs1465222614, COSV60714911; called by muse, mutect2, varscan2
- POGZ | c.1383C>T p.V461= | Silent (SNP) | VAF 73/551 reads (13%) | catalogued as rs1417016555, COSV99652896; called by muse, mutect2, varscan2
- POTEF | c.888G>A p.A296= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100664538; called by muse, varscan2
- QSOX1 | c.756C>A p.L252= | Silent (SNP) | VAF 113/228 reads (50%) | catalogued as COSV62580717; called by muse, mutect2, varscan2
- RFX1 | c.477G>A p.S159= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs763514451, COSV54330612; called by muse, mutect2, varscan2
- ROBO1 | c.2388T>A p.V796= | Silent (SNP) | VAF 132/319 reads (41%) | catalogued as COSV71395585; called by muse, mutect2, varscan2
- RTCB | c.1374G>A p.A458= | Silent (SNP) | VAF 71/311 reads (23%) | catalogued as rs145049274; called by muse, mutect2, varscan2
- SCN2A | c.2304C>T p.C768= | Silent (SNP) | VAF 126/387 reads (33%) | catalogued as rs764479273, COSV99332087; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC23A | c.2055G>A p.L685= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV56975048; called by muse, mutect2, varscan2
- SEMA4D | c.1716G>A p.A572= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs944186384, COSV59392925; called by muse, mutect2, varscan2
- SLC12A4 | c.2142C>T p.F714= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs758875059, COSV50453044; called by muse, mutect2, varscan2
- STMN2 | c.495G>A p.A165= | Silent (SNP) | VAF 974/2078 reads (47%) | catalogued as rs772336347, COSV55220138; called by muse, varscan2
- TSHZ3 | c.1446C>T p.D482= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as rs745403920, COSV53664438, COSV53666789; called by muse, mutect2, varscan2
- AGBL4 | c.1267+84C>G | Intron (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8465G>A | Intron (SNP) | VAF 38/100 reads (38%) | catalogued as rs746676471, COSV100875970; called by muse, mutect2, varscan2
- OBSCN | c.11660-1019C>A | Intron (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99479937; called by muse, mutect2, varscan2
- PFN2 | c.*292C>T | 3'UTR (SNP) | VAF 169/560 reads (30%) | catalogued as rs1055334753, COSV53524001; called by muse, mutect2, varscan2
- Y_RNA | chr14:50091755 G>T | 3'Flank (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
